Gene-level copy-number profile of tumor specimen TCGA-23-1024-01A from TCGA case TCGA-23-1024, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IV; Tumor grade: G3; Age at diagnosis: 52.2 years (19,052 days).
Specimen TCGA-23-1024-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.5b4bb383-e1cd-46a4-a623-a6c7883237dd.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-23-1024-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 815 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/c9c12956-b121-436c-ae9f-f80de3909f21

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 3; copy number 1: 368; copy number 2: 14,202; copy number 3: 21,634; copy number 4: 16,909; copy number 5: 3,395; copy number 6: 637; copy number 7: 788; copy number 8: 1,142; copy number 9: 215; copy number 10: 291; copy number 11: 16; copy number 12: 159; copy number 13: 2; copy number 16: 34; copy number 18: 13.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, sample TCGA-23-1024-01): tumor purity 0.75, ploidy 3.33, whole-genome doublings 1 (call status: legacy_call).

Homozygous deletions (total copy number 0; autosomes only): 3 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr13:68,634,190–68,694,081, 3 genes: RPS3AP52, RPL12P34, RN7SL761P.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 2,660 genes in 13 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr12:40,196,744–44,503,596, 58 genes, copy number 7–18 (within-gene range 3–18): LRRK2, AC084290.1, MUC19, AC107023.1, RNU6-713P, CNTN1, AC016144.1, AC015540.1, PDZRN4, AC090531.1, RNA5SP360, MTND2P17, MTND1P24, LINC02400, AC090630.1, AC006197.1, AC006197.2, AC023513.1, GXYLT1, YAF2, PPHLN1, AC020629.1, ZCRB1, MIR7851, SNORA74, AC079684.1, RNU6-249P, AC079601.2, Y_RNA, PRICKLE1, AC079601.1, AC079600.3, LINC02402, AC079600.2, AC079600.1, LINC02451, RPS27P21, LINC02450, AC068802.1, AC012038.2, AC012038.1, MRPS36P5, LINC02461, ADAMTS20, AC090525.1, AC090525.2, AC090525.3, EEF1A1P17, PUS7L, AC093012.1, IRAK4, TWF1, TMEM117, ZNF75BP, AC025030.2, AC025030.1, AC025253.1, AC025253.2.
- chr13:66,303,871–66,323,561, 1 gene, copy number 11: PCDH9-AS1.
- chr13:70,923,664–71,867,204, 7 genes, copy number 11: MTCL1P1, LINC00348, RABEPKP1, DACH1, H3P36, RPL21P109, RPL35AP31.
- chr14:18,333,726–20,210,498, 99 genes, copy number 9 (broad region; genes not listed).
- chr14:20,343,615–20,357,904, 1 gene, copy number 12 (within-gene range 6–12): PARP2.
- chr14:20,365,667–20,936,255, 38 genes, copy number 12: TEP1, RNA5SP382, KLHL33, AL355075.5, OSGEP, AL355075.2, APEX1, PIP4P1, PNP, AL355075.3, RNASE10, PTCD2P1, SETP1, RNASE9, AL163195.3, RNASE11, AL163195.2, RNASE12, AL163195.1, OR6S1, Y_RNA, ANG, RNASE4, AL163636.1, EGILA, RANBP20P, EDDM3DP, EDDM3A, EDDM3B, RNASE6, AL133371.2, RNASE1, AL133371.3, AL133371.1, RNASE3, AL355922.4, AL355922.3, AL355922.1.
- chr14:73,958,010–77,616,637, 120 genes, copy number 12 (within-gene range 2–12) (broad region; genes not listed).
- chr19:10,133,342–21,852,125, 650 genes, copy number 7 (broad region; genes not listed).
- chr19:27,638,483–31,554,803, 77 genes, copy number 7–16 (broad region; genes not listed).
- chr19:33,795,933–46,746,994, 691 genes, copy number 8 (broad region; genes not listed).
- chr19:50,996,007–52,008,230, 88 genes, copy number 7 (broad region; genes not listed).
- chr20:87,250–20,712,644, 390 genes, copy number 9–10 (within-gene range 3–10) (broad region; genes not listed).
- chr20:46,021,690–64,313,132, 440 genes, copy number 8 (within-gene range 3–8) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 368. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
